HCMI case HCM-WCMC-0749-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c14d7245-1a9c-45cf-b284-8f49c3fe2ec9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Bronchio-alveolar carcinoma, mucinous: ICD-O-3 morphology code: 8253/3; ICD-10 code: C34.32; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 72.6 years (26,530 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IB; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 262 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,788 days (4.9 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 1,206.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- EGFR: Negative.
- EML4–ALK translocation (Sequencing, NOS): Negative; Second exon: 20.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gly12Cys.
- MET: Negative.
- RET rearrangement: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91.5 kg; Height: 177.8 cm; BMI: 29.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 28; Tobacco smoking quit year: 1994.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0749-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0749-C34-01A-S1-HE: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 75; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-0749-C34-01A-S3-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-0749-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0749-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
